Surgical pathology report (de-identified scan), TCGA case TCGA-QG-A5YW, project TCGA-COAD (Colon Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-QG-A5YW-01A (Primary Tumor).

[page 1 of 4]
C6CF ICD-8-3
Adeno carcinoma, mucinous NOS
8480/3
path Adeno carcinoma, NOS
8140/3
Site: Cecum, C18.0
AD 11/16/13

Accession #: Collected:

ADDENDUM- IMMUNOHISTOCHEMISTRY

Results-Comments

The peritoneal nodule shows a well-circumscribed proliferation of spindled cells arranged in fascicles without significant cytologic atypia, necrosis or mitoses. Immunohistochemical stains are expressed as follows:

CD117: negative

CD34: negative

Desmin: positive, diffuse

Interpretation

PERITONEAL NODULE, EXCISION:

- LEIOMYOMA

End of Addendum Report or Additional Results

Staff Pathologist

PATHOLOGIC DIAGNOSIS

ILEUM, CECUM, RIGHT COLON, RIGHT HEMICOLECTOMY:

- TUMOR SITE: CECUM

- TUMOR SIZE: 7.2 X 6.9 X 4.5 CM

- GROSS PERFORATION: NOT IDENTIFIED

- HISTOLOGIC TYPE: ADENOCARCINOMA, WITH FOCAL MUCINOUS AND SIGNET
RING CELL FEATURES

per TSS, 0% mucinous
0% signet ring. Bcr

- HISTOLOGIC GRADE: G2

- MICROSCOPIC TUMOR EXTENSION: TUMOR PENETRATES
INTO SUBSEROSAL FAT

- MARGINS:

[page 2 of 4]
- PROXIMAL: UNINVOLVED BY INVASIVE CARCINOMA
- DISTAL: UNINVOLVED BY INVASIVE CARCINOMA
- MESENTERIC: UNINVOLVED BY INVASIVE CARCINOMA
- LYMPHOVASCULAR INVASION: NOT IDENTIFIED
- PERINEURAL INVASION: NOT IDENTIFIED
- TUMOR DEPOSITS (DISCONTINUOUS EXTRAMURAL EXTENSION): PRESENT (5 FOCI)
- LYMPH NODES: 11/15 LYMPH NODES INVOLVED BY METASTATIC CARCINOMA
- PATHOLOGIC STAGING (pTNM): pT3 pN2b MX
- APPENDIX: NO DIAGNOSTIC PATHOLOGIC ALTERATION
- PERITONEUM: SPINDLE CELL NEOPLASM (SEE COMMENT)

COMMENT: There are deposits of tumor within lymph nodes and the fat approaching the mesenteric margin, but tumor is not identified at the inked margin. The 0.8 cm peritoneal nodule is a spindle cell tumor, and the differential diagnosis includes a gastrointestinal stromal tumor (GIST) and a leiomyoma. Immunohistochemical stains will be performed in order to better characterize this lesion, and results will be issued in an addendum report. The majority of the primary colon tumor has the pattern of a conventional adenocarcinoma, with less than 50% having mucinous or signet ring cell features.

Staff Pathologist

Pertinent Clinical Information

Small white peritoneal nodule adjacent to the right colon.

Gross Description

Specimen Material: Right colon.

The case is received in one part labeled with the patient's name, , medical record number and given accession number and it is accompanied by a requisition form labeled with the same name and same accession number.

The specimen is received fresh in one container as "RIGHT COLON" and consists of 26 cm length of cecum with a diameter of 5.4 cm, 11.3 cm length of terminal ileum, a 2.5 cm diameter, and a 6.3 cm in length appendix with a diameter of 1.2 cm. There is a 9.5 x 5.9 x 3.1 cm portion of mesenteric fat and a 16.0 x 5.9 x 0.6 cm portion of attached pericolic fat. The colonic serosa is tan-pink to tan-red, hemorrhagic. There is a cecal umbilication located 16.5 cm from the proximal margin and 18 cm from the distal margin. The mesentery displays a palpable 4.2 x 3.4 x 1.7 cm mass,

[page 3 of 4]
which extends to the surgical mesenteric margin. The mesenteric margin is inked blue. The serosal umbilication is inked black. There is a 0.8 cm in greatest dimension grey-white hard, ovoid nodule attached to gray-white to tan-pink fibromembranous tissue attached to the cecal serosal surface. The cecal mucosa displays a tan-red to tan-green, 7.2 x 6.9 cm, endophytic, hard, ulcerative, circumferential tumor which obliterates the ileocecal valve. The adjacent appendiceal orifice is located 11.2 cm from the proximal margin and is 9.9 cm from the distal margin. The cut surface of the tumor measures 4.5 cm thick, involves the attached fat and abuts the inked serosa. Multiple lymph nodes are identified ranging from 1.8 to 0.3 cm. Their cut surfaces are grey-white and hard. The cut surface of the mesenteric mass displays that it abuts the mesenteric margin and is gray-white and hard. The appendix is unremarkable. Additional matted lymph nodes are identified ranging from 0.3 to 0.6 cm in diameter.

Representative sections are submitted as follows:

- 1: proximal margin
- 2: distal margin
- 3: full thickness section of cecal tumor
- 4-5: representative section of tumor within mesentery
- 6: tumor to appendiceal orifice
- 7: representative section of uninvolved ileum
- 8: representative section of uninvolved colon
- 9-10: random representative sections of cecal mass
- 11: 2 possible lymph nodes
- 12: lymph node, bisected
- 13: lymph node, bisected
- 14: 2 lymph nodes
- 15: 4 lymph nodes
- 16: 1 bisected lymph node
- 17: 1 bisected lymph node
- 18-19: 2 lymph nodes
- 20: 1 lymph node
- 21: 2 lymph nodes
- 22: 3 lymph nodes
- 23: appendix tip, longitudinal section
- 24: appendix, transverse section
- 25: random section of tumor
- 26: peritoneal nodule
- 27: mesenteric mass to mesenteric margin, perpendicular section
- 28: tumor to inked serosa, full thickness section
- 29-30: tumor in relation to proximal and distal directions, respectively
- 31: two lymph nodes

[page 4 of 4]
Pathology Resident
Microscopic Description
Performed.

This case was reviewed by the staff pathologist listed below.

****Electronically Signed Out****

Staff Pathologist

Criteria	W 3/14/13	Yes	No

Source: NCI Genomic Data Commons file 50f47505-9ef9-42f1-9501-d222ee847c73 (TCGA-QG-A5YW.7DB0BAEA-F194-4372-AF76-9CBEB0F9C956.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).